Somatic mutation profile of tumor specimen MMRF_2236_1_BM_CD138pos (aliquot MMRF_2236_1_BM_CD138pos_T1_KHS5U_L09550) from MMRF case MMRF_2236, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.1 years (21,229 days).
Specimen MMRF_2236_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f95b90d-0f4b-4a26-be63-e64373419e39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2236_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2236_1_PB_Whole_C3_KHS5U_L09551; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8742a0c-c3c1-4629-858d-12d830e8b1a2

The open-access MAF lists 108 somatic variants for this specimen: 40 protein-altering or splice-affecting, 13 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, 3'UTR 25, Intron 20, Silent 13, RNA 4, 5'Flank 3, Frame Shift Del 2, Nonsense Mutation 2, 3'Flank 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CCDC27 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs756765151; called by muse, varscan2
- CCDC71L | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.186); catalogued as rs771314298; called by muse, mutect2, varscan2
- CNKSR3 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.448); catalogued as rs757134142; called by muse, mutect2, varscan2
- ETS2 | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 74/150 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs372145357; called by muse, mutect2, varscan2
- FRAS1 | c.1961C>T p.A654V | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.265); catalogued as rs1479487877; called by muse, mutect2, varscan2
- HSD17B14 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1257748441, COSV99613420; called by muse, mutect2, varscan2
- IGHJ6 | c.43A>C p.T15P | Missense Mutation (SNP) | VAF 36/82 reads (44%) | PolyPhen benign (0.018); catalogued as rs376921777; called by muse, varscan2
- IGHV2-70 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 57/90 reads (63%) | SIFT tolerated (0.31); PolyPhen benign (0.072); catalogued as rs369066675; called by muse, varscan2
- INSR | c.3175G>T p.V1059F | Missense Mutation (SNP) | VAF 47/213 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57176366; called by muse, mutect2, varscan2
- IQCE | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.057); catalogued as rs780175292, COSV58078120; called by muse, mutect2, varscan2
- ORAI1 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 85/205 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs1555324161, COSV57491392; called by muse, mutect2, varscan2
- PAMR1 | c.1955G>T p.W652L (on ENST00000619888 / NM_001001991.3; = p.W669L on NM_015430.4) | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV53510778; called by muse, mutect2, varscan2
- RTN2 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 43/238 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs143302045, COSV55594806; called by muse, mutect2, varscan2
- TENT5C | c.1009G>C p.A337P | Missense Mutation (SNP) | VAF 53/193 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV65616116; called by muse, mutect2, varscan2
- AC126283.2 | c.229A>G p.T77A | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ADNP | c.1225T>A p.S409T | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AKAP1 | c.1019G>A p.R340K | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1601G>A p.G534D | Missense Mutation (SNP) | VAF 66/418 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATAD5 | c.4765T>C p.S1589P | Missense Mutation (SNP) | VAF 155/488 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ATP9A | c.1957G>T p.D653Y | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AUTS2 | c.2459C>T p.S820F | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- BNIP1 | c.74del p.A25Gfs*13 | Frame Shift Del (DEL) | VAF 41/242 reads (17%) | called by mutect2, pindel, varscan2
- DCTN4 | c.7T>G p.S3A | Missense Mutation (SNP) | VAF 153/252 reads (61%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FURIN | c.1144C>G p.L382V | Missense Mutation (SNP) | VAF 56/241 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GPATCH3 | c.917del p.L306Rfs*5 | Frame Shift Del (DEL) | VAF 32/101 reads (32%) | called by mutect2, pindel, varscan2
- HEATR5A | c.1418T>C p.L473S | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KMT2C | c.11122T>C p.S3708P | Missense Mutation (SNP) | VAF 16/383 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- LCOR | c.1921G>C p.A641P | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- LMX1B | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- MYO7B | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 16/268 reads (6%) | called by muse, mutect2
- NLRP11 | c.371T>C p.V124A | Missense Mutation (SNP) | VAF 104/343 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PARD3B | c.36C>G p.I12M | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLA2R1 | c.2254T>C p.S752P | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRDM9 | c.634T>C p.F212L | Missense Mutation (SNP) | VAF 80/352 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- RAB39B | c.290T>G p.F97C | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMC5 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 83/317 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOX30 | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 64/350 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- TRPS1 | c.3133A>T p.S1045C (on ENST00000220888 / NM_001330599.2; = p.S1058C on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/282 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2
- ZNF471 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 90/385 reads (23%) | called by muse, mutect2, varscan2
- ADGRF5 | c.228C>T p.F76= | Silent (SNP) | VAF 66/216 reads (31%) | called by muse, mutect2, varscan2
- AGBL1 | c.678C>T p.S226= | Silent (SNP) | VAF 46/188 reads (24%) | catalogued as rs766934754; called by muse, mutect2, varscan2
- IGHV2-70D | c.297G>A p.V99= | Silent (SNP) | VAF 46/112 reads (41%) | called by muse, varscan2
- IGHV2-70D | c.93G>A p.V31= | Silent (SNP) | VAF 35/126 reads (28%) | called by muse, varscan2
- MICAL2 | c.1944C>T p.S648= | Silent (SNP) | VAF 8/130 reads (6%) | catalogued as rs1434919994; called by muse, mutect2
- MRC1 | c.2793T>C p.A931= | Silent (SNP) | VAF 54/114 reads (47%) | called by muse, mutect2, varscan2
- NLRP11 | c.1110T>C p.H370= | Silent (SNP) | VAF 52/194 reads (27%) | called by muse, mutect2, varscan2
- PHKB | c.1155A>G p.V385= | Silent (SNP) | VAF 27/57 reads (47%) | called by muse, mutect2, varscan2
- PRICKLE1 | c.873T>C p.C291= | Silent (SNP) | VAF 57/156 reads (37%) | catalogued as COSV61543147; called by muse, mutect2, varscan2
- SNX17 | c.393C>T p.V131= | Silent (SNP) | VAF 26/50 reads (52%) | called by muse, mutect2, varscan2
- TSPAN9 | c.78G>A p.G26= | Silent (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- WDR44 | c.2709A>G p.K903= | Silent (SNP) | VAF 104/243 reads (43%) | called by muse, mutect2, varscan2
- WWC2 | c.840G>A p.Q280= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs1252848952; called by muse, mutect2, varscan2
- ACTB | c.-27-195G>C | Intron (SNP) | VAF 66/104 reads (63%) | called by muse, varscan2
- AFDN | c.4812+2295G>T | Intron (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- ARFGEF2 | c.*718T>C | 3'UTR (SNP) | VAF 41/97 reads (42%) | called by muse, mutect2, varscan2
- ARRDC3 | c.*2387G>A | 3'UTR (SNP) | VAF 41/152 reads (27%) | called by muse, mutect2, varscan2
- ASB5 | c.197-16237_197-16194del | Intron (DEL) | VAF 86/469 reads (18%) | called by mutect2, pindel
- BCL2L13 | c.*147A>G | 3'UTR (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- BCL6 | chr3:187721470 G>A | 3'Flank (SNP) | VAF 31/117 reads (26%) | catalogued as rs556072358, COSV51654301; called by muse, mutect2, varscan2
- BMI1 | c.317-48T>A | Intron (SNP) | VAF 28/50 reads (56%) | called by muse, mutect2, varscan2
- C8orf34-AS1 | n.1199_1200del | RNA (DEL) | VAF 28/80 reads (35%) | called by pindel, varscan2
- CDH10 | c.*495T>G | 3'UTR (SNP) | VAF 44/106 reads (42%) | called by muse, mutect2, varscan2
- CDH11 | c.*557T>G | 3'UTR (SNP) | VAF 50/119 reads (42%) | called by muse, mutect2, varscan2
- CDX2 | c.-270C>A | 5'UTR (SNP) | VAF 24/52 reads (46%) | catalogued as rs1030491660; called by muse, mutect2
- CLDN16 | c.*1816A>T | 3'UTR (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- COMMD3 | c.251+12A>C | Intron (SNP) | VAF 68/146 reads (47%) | called by muse, mutect2, varscan2
- ECM2 | c.481+442C>T | Intron (SNP) | VAF 94/161 reads (58%) | called by muse, mutect2, varscan2
- EIF3B | c.2233-57C>T | Intron (SNP) | VAF 26/44 reads (59%) | catalogued as rs1032690535; called by muse, mutect2, varscan2
- ENTHD1 | c.349+11504T>C | Intron (SNP) | VAF 40/116 reads (34%) | called by muse, mutect2, varscan2
- ESRRG | c.*158C>T | 3'UTR (SNP) | VAF 186/382 reads (49%) | called by muse, mutect2, varscan2
- FAM133A | c.*903G>A | 3'UTR (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- FAM162B | c.*110T>G | 3'UTR (SNP) | VAF 14/247 reads (6%) | called by muse, mutect2
- FOXP1 | c.1652+705C>G | Intron (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- GABRB2 | c.1191+30T>C | Intron (SNP) | VAF 40/116 reads (34%) | called by muse, mutect2, varscan2
- GLI3 | c.*1887C>T | 3'UTR (SNP) | VAF 24/110 reads (22%) | called by muse, mutect2, varscan2
- GRIK5 | c.2514+1350G>A | Intron (SNP) | VAF 15/89 reads (17%) | called by muse, mutect2, varscan2
- GYPA | c.37+2282G>A | Intron (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- HAUS6P3 | n.284A>G | RNA (SNP) | VAF 38/179 reads (21%) | called by muse, mutect2, varscan2
- HSD17B12 | c.*1225T>C | 3'UTR (SNP) | VAF 32/83 reads (39%) | called by muse, mutect2, varscan2
- IPMK | c.*4475G>A | 3'UTR (SNP) | VAF 61/163 reads (37%) | catalogued as rs963445338; called by muse, mutect2, varscan2
- KCNK3 | c.*2345del | 3'UTR (DEL) | VAF 67/219 reads (31%) | called by mutect2, pindel, varscan2
- KIF26A | chr14:104180348 del C | 3'Flank (DEL) | VAF 32/92 reads (35%) | called by mutect2, pindel, varscan2
- KRT13 | c.*50A>G | 3'UTR (SNP) | VAF 41/112 reads (37%) | called by muse, mutect2, varscan2
- KRT15 | chr17:41520398 C>T | 5'Flank (SNP) | VAF 17/110 reads (15%) | called by muse, mutect2, varscan2
- LINC01549 | n.637C>T | RNA (SNP) | VAF 12/243 reads (5%) | called by muse, mutect2
- LINC02207 | n.1864T>G | RNA (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- MICA | chr6:31403491 C>T | 5'Flank (SNP) | VAF 44/165 reads (27%) | called by muse, mutect2, varscan2
- NECAP1 | c.383+31T>G | Intron (SNP) | VAF 40/78 reads (51%) | called by muse, mutect2, varscan2
- NEXMIF | c.*421T>C | 3'UTR (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- NLGN1 | c.*2045del | 3'UTR (DEL) | VAF 36/150 reads (24%) | called by mutect2, pindel, varscan2
- PANK1 | c.*351G>T | 3'UTR (SNP) | VAF 45/116 reads (39%) | called by muse, mutect2, varscan2
- PIGW | c.*45G>T | 3'UTR (SNP) | VAF 71/474 reads (15%) | called by muse, mutect2, varscan2
- PITPNM3 | c.*454G>A | 3'UTR (SNP) | VAF 87/294 reads (30%) | called by muse, mutect2, varscan2
- PNKD | c.*182G>A | 3'UTR (SNP) | VAF 10/96 reads (10%) | called by muse, mutect2, varscan2
- POLB | c.551-113T>C | Intron (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- PRPF31 | chr19:54115673 A>T | 5'Flank (SNP) | VAF 29/103 reads (28%) | called by muse, mutect2, varscan2
- PSEN2 | c.788-80G>A | Intron (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- SH2D3C | c.556-3934G>A | Intron (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2, varscan2
- SOX11 | c.*4347del | 3'UTR (DEL) | VAF 5/45 reads (11%) | called by mutect2, varscan2
- SYP | c.*4+493C>T | Intron (SNP) | VAF 86/292 reads (29%) | called by muse, mutect2, varscan2
- TBC1D15 | c.*2095A>G | 3'UTR (SNP) | VAF 37/70 reads (53%) | called by muse, mutect2, varscan2
- TCF7 | c.1149-76G>A | Intron (SNP) | VAF 48/197 reads (24%) | catalogued as rs1041081796; called by muse, mutect2, varscan2
- THSD4 | c.*3148dup | 3'UTR (INS) | VAF 45/187 reads (24%) | catalogued as rs751559575; called by mutect2, varscan2
- TIFA | c.*1557A>G | 3'UTR (SNP) | VAF 111/217 reads (51%) | called by muse, mutect2, varscan2
- TMEM26 | c.*86G>A | 3'UTR (SNP) | VAF 18/34 reads (53%) | catalogued as rs558021039; called by muse, mutect2, varscan2
- TRAPPC12 | c.1531-401G>A | Intron (SNP) | VAF 19/55 reads (35%) | called by muse, mutect2, varscan2
- TRPM3 | c.1154+7854G>T | Intron (SNP) | VAF 10/222 reads (5%) | called by muse, mutect2
